FM case AD16927 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/08fb6a79-aa5b-4024-bff6-1c389211a9fe

Female, 57.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the colon; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
